Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AAEG, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AAEG-01A (Primary Tumor).

[page 1 of 2]
CLINICAL DIAGNOSIS: HCC (S3)

Specimen : liver

Gross Photo :

GROSS:

Specimen state:

Liver: 4.3 x 2.0 x 3.0 cm, 21.8 gm (unfixed)

Operation: Tumorectomy

Lesion:

A well-defined mass (2.0 x 1.3 x 1.3 cm) at segment 3

- Cut surface: Yellowish tan, and granular without necrosis

Gross type

HCC: Expanding nodular

Resection margin: Not involved grossly (safety margin: 1.4 cm)

Others:

Satellite nodule: No

Remaining parenchyma: Cirrhotic

Portal vein invasion: No

Representative sections submitted

Gross photo: Present

Blocks

T1-4, TB, tumor and surrounding liver parenchyme x 5

NB, remaining parenchyme of liver x 1

MICROSCOPIC:

Hepatocellular carcinoma: Yes

Edmondson-Steiner grade

The worst grade III

The major grade III

Histologic type: Trabecular, Pseudoglandular, Compact

ICD-O-3

Carcinoma, hepatocellular NOS

Site: Liver C22.0

QJ 5/20/14

8170/3

[page 2 of 2]
Cell type: Hepatic
Fatty change: No
Fibrous capsule formation: No
Capsular infiltration: No
Septum formation: No
Surgical resection margin invasion: No
Serosal invasion: No
Portal vein invasion: No
Microvessel invasion: No
Intrahepatic metastasis: No
Multicentric occurrence: No

NOT reported. Gross:

NOT reported. Gross:

Vagina, smear, LSIL, HPV infection

Vagina, LSIL, HPV infection

Vagina, smear, suggestive of, bacterial vaginosis

Cervix, punch biopsy, moderate dysplasia

Cervix, LEEP, squamous cell carcinoma in situ, glandular involvement

Liver, segment3, ectomy, hepatocellular carcinoma
T56000, segment3, P10, M81703

DIAGNOSIS:

Liver, segment 3, tumorectomy: Hepatocellular carcinoma

Suggestion :

Source: NCI Genomic Data Commons file f5911171-4584-43ba-84a7-14bb52aaaa93 (TCGA-DD-AAEG.B48B65B0-92F9-4B49-B8A8-563EA5AF70F1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).